Gene-level copy-number profile of tumor specimen C3L-02219-01 from CPTAC case C3L-02219, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 77.6 years (28,347 days).
Specimen C3L-02219-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 478395e7-4b51-4ebb-a5fb-c30512c55dcd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02219-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/8644b0ee-07f3-4963-8e9d-310546f4f9f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 12,759; copy number 2: 40,486; copy number 3: 4,078; copy number 4: 557; copy number 5: 50; copy number 6: 650; copy number 7: 44; copy number 8: 8; copy number 9: 7; copy number 11: 58; copy number 17: 12; copy number 20: 83; copy number 21: 15; copy number 24: 28; copy number 25: 9; copy number 28: 62.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,846,097–143,846,504, 1 gene: AC239798.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,026 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–143,500,512, 7 genes, copy number 5: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799.
- chr5:58,198–693,352, 27 genes, copy number 5–8: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:795,606–45,895,970, 650 genes, copy number 6 (broad region; genes not listed).
- chr8:7,955,014–8,024,652, 7 genes, copy number 8: FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P.
- chr12:56,521,820–72,186,618, 335 genes, copy number 5–28 (within-gene range 1–28) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,650. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
